Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7312, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7312-01B (Primary Tumor).

Collection Date: [REDACTED]

FINAL DIAGNOSIS:

PART 1: PROSTATE AND BILATERAL SEMINAL VESICLES, ROBOTIC RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.7 CM.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE LEFT ANTERIOR BASE AND THE LEFT POSTERIOR BASE REGIONS (SLIDES 1T AND 1Z).
- F. LEFT SEMINAL VESICLE INVOLVED BY INVASIVE CARCINOMA (see comment).
- G. RIGHT SEMINAL VESICLE IS FREE OF CARCINOMA (see comment).
- H. LEFT ANTERIOR APEX AND LEFT POSTERIOR BASE MARGINS FOCALLY INVOLVED BY CARCINOMA (SLIDES 1Q AND 1C); REMAINING SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA (see comment).
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3b N0 MX.
- M. TNM HISTOLOGIC GRADE = G3-4.
- N. BENIGN PROSTATIC HYPERTROPHY, AND CHRONIC MILDLY ACTIVE PROSTATITIS WITH FOCAL ATROPHIC CHANGES ARE NOTED.

PART 2: LYMPH NODES, BILATERAL PELVIC, EXCISION –

THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

COMMENT:

The patient's prior biopsy results showing prostatic adenocarcinoma involving the right lobe of the prostate, and high grade prostatic intraepithelial neoplasia involving the left lobe of the prostate is noted.

The tumor involves the left seminal vesicle and the adjacent cauterized surgical margin approximates the right seminal vesicle muscular wall. Tumor closely

Immunohistochemical stains performed on block 1Q for AMACR/P504S shows focal positivity in glands with loss of p63 basal cell stain. The histomorphologic and immunohistochemical findings support the above diagnoses. Immunohistochemical stain to cytokeratin p903 is noncontributory.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 8
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	70%
WEIGHT OF PROSTATE:	41.73gm
TUMOR SIZE:	Maximum dimension: 1.7 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
RESIDUAL TUMOR:	R1
LYMPH NODES EXAMINED:	3
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 9bea94f6-8fe2-4e05-adaa-143256e2b57b (TCGA-EJ-7312.92D81258-C134-48A6-8B74-DE3789E1530F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).